Somatic mutation profile of tumor specimen 0DYB0X from CCDI case PBCSCJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.6 years (6,442 days).
Specimen 0DYB0X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70e290e2-b4c4-4b57-b73d-676fbbf7068d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYB0L (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e36525cf-ffaa-4c54-bbec-cddb3a86ab49

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP47 | c.8269G>C p.G2757R | Missense Mutation (SNP) | VAF 102/1016 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as rs1451899167; called by muse, mutect2
- LAMA2 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 79/471 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768766369, COSV70341773, COSV70343373; called by muse, varscan2
- UGT2B28 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 273/808 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs371477713; called by muse, mutect2, varscan2
- ZNF843 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 148/339 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.441); catalogued as rs1300721016; called by muse, mutect2, varscan2
- ERBIN | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 76/698 reads (11%) | called by muse, mutect2, varscan2
- KIAA1671 | c.3446G>A p.S1149N | Missense Mutation (SNP) | VAF 55/264 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KLF11 | c.1088A>G p.N363S | Missense Mutation (SNP) | VAF 38/506 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.018); called by muse, mutect2
- RAPGEF2 | c.147T>A p.S49R | Missense Mutation (SNP) | VAF 27/838 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- CDCP2 | c.837C>T p.N279= | Silent (SNP) | VAF 49/255 reads (19%) | called by muse, mutect2, varscan2
- IGSF10 | c.1590A>T p.I530= | Silent (SNP) | VAF 70/394 reads (18%) | called by muse, mutect2, varscan2
- LRRC8C | c.993A>G p.G331= | Silent (SNP) | VAF 178/496 reads (36%) | catalogued as rs1472499992; called by muse, mutect2, varscan2
- LTBP4 | c.48G>T p.L16= | Silent (SNP) | VAF 12/263 reads (5%) | called by muse, mutect2
- LRRC7 | c.1421-34A>T | Intron (SNP) | VAF 19/232 reads (8%) | catalogued as rs1415560984; called by mutect2, varscan2
